Gene-level copy-number profile of tumor specimen C3N-02373-03 from CPTAC case C3N-02373, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 67.0 years (24,460 days).
Specimen C3N-02373-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file fd0e7aec-1f31-410f-ac6c-385c4573683f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02373-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,719 have no estimate.
https://portal.gdc.cancer.gov/files/160f85e2-677f-4c9a-9b0d-aa6b393f39e7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 474; copy number 1: 12,096; copy number 2: 37,391; copy number 3: 8,141; copy number 4: 236; copy number 5: 99; copy number 6: 53; copy number 7: 50; copy number 8: 31; copy number 9: 68; copy number 10: 21; copy number 11: 54; copy number 12: 24; copy number 13: 10; copy number 14: 11; copy number 15: 2; copy number 16: 20; copy number 17: 20; copy number 19: 49; copy number 20: 2; copy number 21: 22; copy number 23: 8; copy number 25: 9; copy number 27: 7; copy number 31: 6.

Homozygous deletions (total copy number 0; autosomes only): 474 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,502,145–49,508,806, 2 genes: ANKRD20A17P, AC119751.5.
- chr6:45,197,674–45,197,770, 1 gene (within-gene range 0–2): MIR586.
- chr10:78,179,174–78,675,109, 3 genes (within-gene range 0–1): AC012560.1, LINC00595, AC010163.3.
- chr10:78,352,597–79,893,175, 33 genes: AC010163.2, SNORA71, AL583852.1, AC016820.1, ZMIZ1-AS1, AL356753.1, ZMIZ1, PPIF, ZCCHC24, AL133481.1, TPRX1P1, AL133481.3, AL133481.2, EIF5AL1, BX248123.1, RPS12P18, SFTPA2, MBL3P, SFTPA3P, SFTPA1, LINC02679, AL132656.2, NUTM2B-AS1, AL132656.3, AL132656.4, BEND3P3, AL132656.1, NUTM2B, AL135925.1, NUTM2E, NPAP1P2, CTSLP6, PGGT1BP2.
- chr11:67,965,873–70,436,584, 72 genes (broad region; genes not listed).
- chr11:70,477,277–70,604,859, 2 genes (within-gene range 0–1): AP001271.1, AP001271.2.
- chr22:19,667,023–24,774,720, 361 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 566 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–1,728,172, 62 genes, copy number 9–31 (broad region; genes not listed).
- chr5:6,686,325–6,757,044, 2 genes, copy number 7: LINC02102, TENT4A.
- chr5:10,070,531–10,082,772, 2 genes, copy number 7: AC091905.1, AC091905.4.
- chr5:133,052,013–133,106,449, 1 gene, copy number 5 (within-gene range 3–5): HSPA4.
- chr11:66,509,079–67,524,517, 57 genes, copy number 5–19 (within-gene range 1–19): AP002748.5, BBS1, AP002748.6, ZDHHC24, ACTN3, AP002748.2, CTSF, CCDC87, CCS, RNU4-39P, RBM14, RBM14-RBM4, RBM4, RBM4B, SPTBN2, RN7SL12P, C11orf80, C1QBPP2, FTLP6, RCE1, PC, LRFN4, RNU7-23P, MIR3163, C11orf86, SYT12, MIR6860, RHOD, KDM2A, AP001885.1, AP001885.3, GRK2, ANKRD13D, SSH3, RAD9A, POLD4, AP003419.1, AP003419.2, RN7SKP239, CLCF1, AP003419.3, RNU6-1238P, PPP1CA, TBC1D10C, CARNS1, RPS6KB2, RPS6KB2-AS1, PTPRCAP, CORO1B, GPR152, CABP4, TMEM134, AIP, MIR6752, PITPNM1, CDK2AP2, CABP2.
- chr11:92,161,106–92,161,889, 1 gene, copy number 8: RPL7AP57.
- chr11:93,144,174–93,197,991, 1 gene, copy number 5 (within-gene range 1–5): SLC36A4.
- chr11:93,171,134–93,241,168, 4 genes, copy number 5: AP003072.5, AP003072.3, AP003072.1, AP003969.1.
- chr11:94,185,439–94,282,203, 1 gene, copy number 16 (within-gene range 1–16): AP002784.1.
- chr11:95,571,040–96,514,748, 16 genes, copy number 16–23 (within-gene range 16–31): AP000820.2, AP000820.1, AP001877.1, FAM76B, CEP57, MTMR2, RNA5SP345, AP000870.1, MAML2, AP000779.1, MIR1260B, CCDC82, JRKL, JRKL-AS1, RNA5SP346, LINC02737.
- chr11:97,878,475–97,959,558, 2 genes, copy number 17: LINC02713, AP003730.1.
- chr11:98,565,074–98,945,079, 3 genes, copy number 8–15: AP003038.1, AP003715.1, AP002428.1.
- chr11:132,403,360–132,404,060, 1 gene, copy number 5: AP000843.1.
- chr11:134,671,426–135,075,908, 7 genes, copy number 5–15: AP001999.1, LINC02706, LINC02714, AP003062.2, LINC02697, AP003062.1, LINC02684.
- chr14:18,333,726–18,412,264, 3 genes, copy number 5: CR383658.1, RNU6-458P, CR383658.2.
- chr15:30,103,720–30,625,773, 35 genes, copy number 5 (within-gene range 3–5): ULK4P3, U8, GOLGA8T, RN7SL469P, DNM1P30, AC120045.2, AC120045.1, LINC02249, AC135731.1, RNU6-17P, AC135731.2, AC019322.4, Y_RNA, CHRFAM7A, AC019322.1, U8, AC019322.3, GOLGA8R, RN7SL196P, AC019322.2, AC127502.1, AC127502.2, AC127502.3, AC026150.2, AC026150.1, GOLGA8Q, RN7SL796P, DNM1P50, ULK4P2, U8, GOLGA8H, AC026150.3, RN7SL628P, AC091057.3, AC091057.2.
- chr22:24,806,169–24,946,695, 3 genes, copy number 6: SGSM1, AL049759.1, TMEM211.
- chr22:37,952,607–38,041,915, 1 gene, copy number 20 (within-gene range 4–20): POLR2F.
- chr22:37,988,794–37,988,853, 1 gene, copy number 20 (within-gene range 4–20): MIR4534.
- chr22:38,078,134–44,010,531, 217 genes, copy number 5–27 (within-gene range 3–27) (broad region; genes not listed).
- chr22:44,172,956–44,366,284, 5 genes, copy number 5: PARVG, AL031595.1, AL031595.2, SHISAL1, Z85994.1.
- chr22:44,606,939–45,977,162, 31 genes, copy number 6–9 (within-gene range 4–9): LINC00229, ANP32BP2, PRR5, PRR5-ARHGAP8, ARHGAP8, PHF21B, Z83838.1, AL079301.1, NUP50-DT, Z82243.1, NUP50, AL008718.3, KIAA0930, MIR1249, AL008718.2, AL008718.1, UPK3A, FAM118A, SMC1B, RIBC2, AL021391.1, FBLN1, LINC01589, RNU6-1161P, Z95331.1, ATXN10, MIR4762, Z84478.1, BX324167.2, BX324167.1, WNT7B.
- chr22:46,150,521–50,801,309, 110 genes, copy number 5–19 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 9,289. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
